MMRF case MMRF_2498 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bc746271-9b4e-49fa-a96e-30bfd6c9001a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 43.2 years (15,762 days); ISS stage: I; Days to last known disease status: 635 days (1.7 years); Days to last follow up: 635 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 111 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 173 days; Days to treatment end: 173 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 174 days; Days to treatment end: 174 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 4.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.747 mg/dL; Immunoglobulin G 61.7 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.83 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 10.8 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 0.35 mg/dL.
- Day 55 (ECOG 0): M Protein 0.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 4.29 mmol/L.
- Day 153 (ECOG 0): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.609 mg/dL; Immunoglobulin G 8.71 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.9 mmol/L.
- Day 229 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.209 mg/dL; Immunoglobulin G 6.81 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.89 mmol/L.
- Day 387: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.58 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 4.9 mmol/L.
- Day 446 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 162 ×10⁹/L.
- Day 513: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.858 mg/dL; Immunoglobulin G 9.63 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.83 mmol/L.
- Day 635 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.84 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day -7: Weight: 100 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2498_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2498_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
